TCGA case TCGA-BQ-7056 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/36182304-2db7-446a-929c-7e43a47d863a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (3)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 75.2 years (27,467 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T3a; AJCC clinical N: NX; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 612 days (1.7 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temsirolimus; Initial disease status: Progressive Disease; Days to treatment start: 638 days (1.7 years); Days to treatment end: 730 days (2.0 years); Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Days to treatment start: 759 days (2.1 years); Prescribed dose: 37.5; Prescribed dose units: mg; Route of administration: Oral.
2. Malignant fibrous histiocytoma: ICD-O-3 morphology code: 8830/3; Tissue or organ of origin: Lower limb, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Doxorubicin Hydrochloride; Days to treatment start: -2,619 days (-7.2 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -2,442 days (-6.7 years); Treatment anatomic sites: Locoregional Site.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 75.6 years (27,610 days); Days to diagnosis: 143 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS to Distant Site.

Follow-up (2 entries)
- Day 143 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 612 days (1.7 years); Disease response: With Tumor.

Molecular and laboratory tests
- Hemoglobin: Low.
- Leukocytes: Elevated.
- Calcium: Normal.
- Platelets: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 113.4 kg; Height: 173 cm; BMI: 37.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BQ-7056-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-BQ-7056-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-BQ-7056-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-BQ-7056-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BQ-7056-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.7; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes; Tobacco smoking history indicator: 3.
- Drug treatment 1: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastasis.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Follow-up form: Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Thigh.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -3021.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: Adriamycin.
- Other malignancy form, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy malignant fibrous histiocytoma treated with Adriamycin and locoregional radiation.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 612 days; disease-specific survival: no event (censored), 612 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 143 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BQ-7056-01): tumor purity 0.83, ploidy 1.95, whole-genome doublings 0 (call status: maf_call).
